Somatic mutation profile of tumor specimen TCGA-CG-5728-01A (aliquot TCGA-CG-5728-01A-11D-1600-08) from TCGA case TCGA-CG-5728, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CG-5728-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5c19f11-83c7-4c9a-ac79-f544e214e1a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5728-11A (Solid Tissue Normal), aliquot TCGA-CG-5728-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9427b9c5-7af1-4756-b90b-b228fbdd85b0

The open-access MAF lists 1,646 somatic variants for this specimen: 1,260 protein-altering or splice-affecting, 353 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 781, Silent 353, Frame Shift Del 338, Frame Shift Ins 64, Nonsense Mutation 29, Splice Site 22, In Frame Del 18, Intron 9, Splice Region 8, 3'UTR 7, 5'Flank 6, 3'Flank 5.

Variants (750 of 1,646; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.4397G>A p.R1466Q | Missense Mutation (SNP) | VAF 22/101 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen possibly damaging (0.897); catalogued as rs749770110, COSV53727699, COSV53731619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CFTR | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121909031, CD920989, CM940240, COSV50101514; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EYS | c.179del p.L60Wfs*3 | Frame Shift Del (DEL) | VAF 65/289 reads (22%) | catalogued as rs786205652, CD157904; ClinVar: likely pathogenic; called by mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MAP2K4 | c.891+2T>C p.X297_splice | Splice Site (SNP) | VAF 22/141 reads (16%) | hotspot (GDC flag); catalogued as COSV62255139, COSV62261780; called by muse, mutect2, varscan2
- MFRP | chr11:119345563 del G | 5'Flank (DEL) | VAF 11/101 reads (11%) | catalogued as rs587776596, CD052468, COSV64129114; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 82/268 reads (31%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 25/224 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | catalogued as rs121913289; ClinVar: pathogenic; called by pindel, varscan2*
- SH3TC2 | c.2710C>T p.R904* | Nonsense Mutation (SNP) | VAF 75/332 reads (23%) | catalogued as rs80338931, CM064264; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMPD1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs989639224, CM023137, COSV54970720; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 61/336 reads (18%) | catalogued as rs746497630; called by mutect2, varscan2
- AARD | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs1354496261, COSV65600422; called by muse, mutect2
- ABCA8 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52212256; called by muse, mutect2, varscan2
- AC093827.5 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55745764; called by muse, mutect2, varscan2
- ACAD11 | c.1455G>T p.E485D | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV51443516; called by muse, mutect2, varscan2
- ACAP2 | c.1128G>C p.K376N | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as COSV58755895; called by muse, mutect2, varscan2
- ACCS | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.752); catalogued as rs1455669046, COSV55459353; called by muse, varscan2
- ACOX1 | c.1107G>T p.E369D | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV53136688; called by muse, mutect2, varscan2
- ACOX3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV62713790; called by muse, mutect2, varscan2
- ACTA1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as CM095302, CM095303, COSV64203373; called by muse, mutect2, varscan2
- ACTA2 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs766734961, COSV56518179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR1C | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54643794; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 92/228 reads (40%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM21 | c.862T>C p.S288P | Missense Mutation (SNP) | VAF 19/299 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV50809708; called by muse, mutect2
- ADAM28 | c.1039A>T p.M347L | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56105461; called by muse, mutect2, varscan2
- ADAM32 | c.2238C>T p.S746= | Splice Region (SNP) | VAF 29/170 reads (17%) | catalogued as COSV65953699; called by muse, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 40/210 reads (19%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS2 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749842152, COSV99281726; called by muse, varscan2
- ADAMTS5 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs766100243, COSV53182969; called by muse, mutect2
- ADCK1 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs758294837, COSV53078469; called by muse, mutect2, varscan2
- ADCY1 | c.2881G>A p.V961I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.318); catalogued as rs373406969; called by muse, mutect2, varscan2
- ADCY7 | c.2833G>A p.V945I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs150764665; called by muse, mutect2, varscan2
- ADD3 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53325941; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA3 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750505698, COSV51561810; called by muse, mutect2, varscan2
- ADGRG4 | c.9019C>T p.R3007* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as rs1310086936, COSV54960379; called by muse, mutect2
- ADHFE1 | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52559199; called by muse, mutect2, varscan2
- ADK | c.244T>G p.S82A (on ENST00000286621; = p.S65A on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV54219179; called by muse, mutect2, varscan2
- ADPRS | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs368062351; called by muse, mutect2, varscan2
- AEBP1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs771452124, COSV56257196; called by muse, varscan2
- AFDN | c.2731G>A p.D911N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60042096; called by muse, mutect2
- AFF1 | c.547G>T p.G183* | Nonsense Mutation (SNP) | VAF 39/176 reads (22%) | catalogued as rs148083475, COSV57124068; called by muse, mutect2, varscan2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as COSV58317085; called by mutect2, pindel
- AGBL5 | c.1266dup p.K423Qfs*28 | Frame Shift Ins (INS) | VAF 35/296 reads (12%) | catalogued as rs747733044; called by mutect2, varscan2
- AGGF1 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.677); catalogued as rs747968547, COSV57231253; called by muse, mutect2, varscan2
- AGK | c.1094G>A p.C365Y | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62595969; called by muse, mutect2, varscan2
- AHNAK2 | c.7175C>T p.P2392L | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs778113710, COSV60930585; called by muse, mutect2, varscan2
- AHRR | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1243610648, COSV100328030; called by muse, mutect2
- AIFM1 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200114054, COSV54857791; ClinVar: benign; called by muse, mutect2, varscan2
- AKAP10 | c.1325A>G p.Y442C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294758516, COSV56733145; called by muse, mutect2
- AKR1C3 | c.698del p.P233Rfs*22 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as COSV65910135; called by mutect2, varscan2
- ALDH1A1 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 24/160 reads (15%) | catalogued as COSV52794338; called by muse, mutect2, varscan2
- AMACR | c.1126A>G p.N376D | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56875495; called by muse, mutect2, varscan2
- AMPD2 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56650699; called by muse, mutect2, varscan2
- ANAPC5 | c.759G>A p.A253= | Splice Region (SNP) | VAF 39/194 reads (20%) | catalogued as rs374015840, COSV55843091; called by muse, mutect2, varscan2
- ANGEL1 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs759294719, COSV51872041; called by muse, mutect2, varscan2
- ANKIB1 | c.2522A>G p.D841G | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV56066108; called by muse, mutect2, varscan2
- ANKLE2 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.673); catalogued as rs771035135, COSV61709248; called by muse, mutect2, varscan2
- ANKRD1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 64/365 reads (18%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs746392266, COSV65468067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD23 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1423111422, COSV58412729; called by muse, mutect2, varscan2
- ANKRD30A | c.3514A>G p.I1172V (on ENST00000611781; = p.I1116V on NM_052997.2) | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV64621378; called by muse, mutect2, varscan2
- ANKRD44 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774090343, COSV56550946; called by muse, mutect2, varscan2
- ANKRD52 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1489734027, COSV57287498; called by muse, mutect2, varscan2
- ANKS6 | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62052213; called by muse, mutect2, varscan2
- ANO2 | c.2033G>A p.S678N (on ENST00000356134 / NM_001278597.3; = p.S682N on NM_001278596.3) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs1446261077, COSV59043304; called by muse, mutect2, varscan2
- ANXA9 | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV64485605; called by muse, mutect2
- AOX1 | c.1347del p.F449Lfs*44 | Frame Shift Del (DEL) | VAF 24/154 reads (16%) | catalogued as COSV65981536; called by mutect2, pindel, varscan2
- AP2B1 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV52003487; called by muse, mutect2, varscan2
- AP3B2 | c.1454T>A p.I485N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55611103, COSV55614363; called by muse, mutect2, varscan2
- APLP1 | c.1658C>T p.A553V (on ENST00000221891 / NM_001024807.3; = p.A552V on NM_005166.4) | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1156249745, COSV55705407; called by muse, mutect2
- APOF | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV58477405; called by muse, mutect2, varscan2
- APOH | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs113544357, COSV52775014; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP6 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 74/358 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59646925; called by muse, mutect2, varscan2
- ARHGAP25 | c.916A>G p.N306D (on ENST00000409202 / NM_001007231.3; = p.N298D on NM_014882.3) | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54909139; called by muse, mutect2
- ARHGAP25 | c.1094del p.P365Lfs*17 (on ENST00000409202 / NM_001007231.3; = p.P357Lfs*17 on NM_014882.3) | Frame Shift Del (DEL) | VAF 56/318 reads (18%) | catalogued as rs1004388629; called by mutect2, pindel, varscan2
- ARHGAP31 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV51790140; called by muse, mutect2
- ARHGAP33 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.085); catalogued as rs1307060453, COSV50165190; called by muse, mutect2, varscan2
- ARHGAP39 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs751287574, COSV52775821; called by muse, varscan2
- ARHGEF15 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs766441392, COSV62726461; called by muse, mutect2, varscan2
- ARHGEF18 | c.1507G>A p.A503T (on ENST00000359920 / NM_001130955.2; = p.A399T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60473962; called by muse, mutect2, varscan2
- ARHGEF26 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.876); catalogued as rs1442950279, COSV62851969; called by muse, mutect2, varscan2
- ARHGEF37 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775205811, COSV61369997; called by muse, mutect2, varscan2
- ARID1B | c.4853T>A p.I1618N | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs984561078, COSV51681062; called by muse, mutect2, varscan2
- ARL13A | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.021); catalogued as COSV65880355; called by muse, mutect2, varscan2
- ARMC2 | c.2588C>A p.P863H | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV64553344; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63439055; called by muse, mutect2, varscan2
- ARSI | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs775003019, COSV60817428, COSV60818502; called by muse, mutect2
- ASAP2 | c.1111+1G>A p.X371_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as COSV55638714; called by muse, mutect2, varscan2
- ASB6 | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52965901; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 64/261 reads (25%) | catalogued as rs761154268; called by mutect2, varscan2
- ASH2L | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs1302966083, COSV51701778; called by muse, mutect2, varscan2
- ASTN1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.989); catalogued as rs369470818; called by muse, mutect2, varscan2
- ASTN2 | c.3866G>A p.R1289H (on ENST00000313400 / NM_001365069.1; = p.R1238H on NM_014010.5) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs139072409; called by muse, mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATG2A | c.1895C>T p.T632M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs367636075; called by muse, mutect2, varscan2
- ATP10A | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763990614, COSV63515700; called by muse, mutect2, varscan2
- AUNIP | c.132_135del p.K45Lfs*58 | Frame Shift Del (DEL) | VAF 18/147 reads (12%) | catalogued as rs1200449724; called by pindel, varscan2
- BACH2 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as COSV57609077; called by muse, mutect2, varscan2
- BAZ2B | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 31/408 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.702); catalogued as rs1339081290, COSV58609928; called by muse, mutect2
- BBS9 | c.328+1G>A p.X110_splice | Splice Site (SNP) | VAF 8/54 reads (15%) | catalogued as COSV54187499; called by mutect2, varscan2
- BCAN | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV61256258; called by muse, mutect2, varscan2
- BCAN | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV100228516; called by muse, mutect2, varscan2
- BCR | c.1472A>G p.D491G | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs367931519; called by muse, mutect2, varscan2
- BHLHE23 | c.406C>T p.R136C (on ENST00000370346; = p.R152C on NM_080606.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781619083, COSV64846585; called by muse, mutect2, varscan2
- BICD2 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.887); catalogued as rs766539334, COSV63548502; called by muse, mutect2, varscan2
- BMS1 | c.3736G>A p.E1246K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.073); catalogued as rs767197742, COSV65735482; called by muse, mutect2, varscan2
- BNC2 | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66157303; called by muse, varscan2
- BRCA1 | c.1103A>G p.E368G | Missense Mutation (SNP) | VAF 40/595 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV58799576; called by muse, mutect2
- BRINP3 | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs760188757, COSV66537031; called by muse, mutect2, varscan2
- BRMS1L | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.456); catalogued as COSV53764537; called by muse, mutect2
- BSN | c.7513del p.T2506Hfs*63 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | catalogued as rs754418611; called by mutect2, pindel, varscan2
- C10orf90 | c.1600A>G p.T534A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV52964127; called by muse, mutect2, varscan2
- C19orf47 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs763108351, COSV63511139; called by muse, mutect2, varscan2
- C1QBP | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); catalogued as rs371917632; called by muse, mutect2, varscan2
- C1orf141 | c.363del p.K121Nfs*12 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs145606616, COSV63992899; called by mutect2, varscan2
- C2CD5 | c.2307C>A p.C769* | Nonsense Mutation (SNP) | VAF 16/147 reads (11%) | catalogued as COSV61727690; called by muse, mutect2, varscan2
- C2orf78 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs946908285, COSV68517882; called by muse, mutect2, varscan2
- C3 | c.4765A>G p.K1589E | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as COSV55577591; called by muse, mutect2, varscan2
- C3 | c.3489C>T p.N1163= | Splice Region (SNP) | VAF 14/108 reads (13%) | catalogued as rs375600369; called by muse, mutect2, varscan2
- C4orf50 | c.8G>A p.R3Q (on ENST00000324058; = p.R1235Q on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367942099; called by muse, mutect2, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs747591930; called by mutect2, varscan2
- CACNA2D4 | c.1820T>C p.M607T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54960274; called by muse, mutect2, varscan2
- CADPS | c.3694G>A p.A1232T | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as rs1238715963, COSV51894156; called by muse, mutect2
- CAMTA2 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV61835996; called by muse, mutect2, varscan2
- CAND1 | c.3644T>C p.I1215T | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV73389784; called by muse, mutect2, varscan2
- CAND2 | c.1139T>C p.V380A (on ENST00000456430 / NM_001162499.2; = p.V287A on NM_012298.3) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55994642; called by muse, mutect2, varscan2
- CARMIL1 | c.1685T>C p.I562T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs1276996782, COSV61523853; called by muse, mutect2, varscan2
- CASQ1 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as COSV63624550; called by muse, mutect2, varscan2
- CASZ1 | c.4204C>T p.R1402C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs772002077, COSV65461100; called by muse, mutect2, varscan2
- CASZ1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs754266033, COSV59741008; called by muse, mutect2, varscan2
- CCDC116 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764612340, COSV53038792; called by muse, mutect2, varscan2
- CCDC170 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs1159721192, COSV53339314, COSV53340316; called by muse, mutect2, varscan2
- CCDC171 | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); catalogued as rs777107054, COSV52653116; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 21/151 reads (14%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 37/89 reads (42%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC71 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1230183688, COSV58910744; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as rs747079826; called by mutect2, varscan2
- CCM2 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51851391; called by muse, mutect2, varscan2
- CCNE1 | c.1008G>T p.M336I | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV52905794; called by muse, mutect2, varscan2
- CCNK | c.978G>T p.Q326H | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV66275854; called by muse, mutect2, varscan2
- CCNL2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68767051; called by muse, mutect2, varscan2
- CCS | c.759G>T p.E253D | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV100040051, COSV59580593; called by muse, mutect2, varscan2
- CCT5 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 49/263 reads (19%) | catalogued as COSV54725493; called by muse, mutect2, varscan2
- CD14 | c.932G>T p.R311M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV57371438; called by muse, mutect2, varscan2
- CDC42BPG | c.1292G>T p.R431M | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV61349210; called by muse, mutect2, varscan2
- CDH12 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 49/252 reads (19%) | catalogued as COSV66448227; called by muse, mutect2, varscan2
- CDH18 | c.938T>C p.M313T | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1166724224, COSV56961224; called by muse, mutect2, varscan2
- CDH20 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV53004433; called by muse, mutect2, varscan2
- CDK12 | c.4382dup p.T1463Nfs*50 (on ENST00000447079 / NM_016507.4; = p.T1454Nfs*50 on NM_015083.3) | Frame Shift Ins (INS) | VAF 18/111 reads (16%) | catalogued as rs760014508; called by mutect2, varscan2
- CDK16 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV52093895; called by muse, mutect2, varscan2
- CDNF | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65806278; called by muse, mutect2, varscan2
- CDYL2 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346545104, COSV73654985; called by muse, mutect2, varscan2
- CEBPZ | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs527616050, COSV50018906; called by muse, mutect2, varscan2
- CEL | c.1547C>T p.T516M (on ENST00000673714; = p.T513M on NM_001807.6) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs762461399, COSV60826847; called by muse, mutect2, varscan2
- CELSR1 | c.5491G>C p.V1831L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.484); catalogued as COSV53099872; called by muse, mutect2, varscan2
- CELSR3 | c.1784T>C p.I595T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV51151263; called by muse, mutect2, varscan2
- CEP128 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs561372195, COSV53676499; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 28/162 reads (17%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP57 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779052991, COSV63016846; called by muse, varscan2
- CFAP69 | c.1872del p.K624Nfs*5 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs763364101; called by mutect2, varscan2
- CFAP74 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs566126731, COSV54573912; called by muse, mutect2, varscan2
- CFH | c.2654G>T p.R885M | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1184020128, COSV66413521; called by muse, mutect2, varscan2
- CHAF1A | c.1576T>C p.S526P | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV56676407; called by muse, mutect2, varscan2
- CHAT | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1471251847, COSV60329821, COSV60333129; called by muse, mutect2, varscan2
- CHCHD3 | c.369+2T>C p.X123_splice | Splice Site (SNP) | VAF 27/143 reads (19%) | catalogued as COSV52783239; called by muse, mutect2, varscan2
- CHD3 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); catalogued as COSV57880283; called by muse, mutect2
- CHD3 | c.2550G>T p.E850D | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV57873857; called by muse, mutect2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 77/501 reads (15%) | catalogued as rs1322050057; called by pindel, varscan2
- CHD8 | c.3535A>G p.I1179V (on ENST00000646647 / NM_001170629.2; = p.I900V on NM_020920.4) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67872691; called by muse, varscan2
- CHD9 | c.7291del p.R2431Gfs*8 (on ENST00000398510 / NM_001382353.1; = p.R2415Gfs*8 on NM_025134.7) | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs748826986; called by mutect2, varscan2
- CHERP | c.2090C>T p.P697L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52227745; called by muse, mutect2
- CHMP7 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs769951659, COSV57532204; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as rs751548647; called by mutect2, varscan2
- CHST2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58887068; called by muse, mutect2
- CIITA | c.1381del p.D461Mfs*28 | Frame Shift Del (DEL) | VAF 23/137 reads (17%) | catalogued as COSV60855989; called by mutect2, pindel, varscan2
- CIITA | c.3376C>T p.R1126W | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60862083; called by muse, mutect2, varscan2
- CLASP2 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs534242099, COSV56293945; called by muse, mutect2
- CLCNKB | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs779798035, COSV65159471; called by muse, mutect2, varscan2
- CLCNKB | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750155699, COSV65161782; called by muse, mutect2, varscan2
- CLDN4 | c.379T>A p.L127M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV52897198; called by muse, mutect2, varscan2
- CLINT1 | c.1736T>C p.M579T | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV51629031; called by muse, mutect2, varscan2
- CLTC | c.4074G>A p.W1358* | Nonsense Mutation (SNP) | VAF 7/125 reads (6%) | catalogued as COSV52253118, COSV99292523; called by muse, mutect2
- CLTCL1 | c.2875G>A p.V959I | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs188611399, COSV54230542, COSV54239297; called by muse, mutect2, varscan2
- CMTM4 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58063709; called by muse, mutect2, varscan2
- CMYA5 | c.6917T>C p.V2306A | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV71409488; called by muse, mutect2, varscan2
- CNGA4 | c.160T>G p.C54G | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV56414777; called by muse, mutect2
- CNOT6 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1561663748, COSV56164076; called by muse, mutect2, varscan2
- CNTN2 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255290042, COSV59352958; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 34/152 reads (22%) | catalogued as rs758676375; called by mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs374805044; called by mutect2, varscan2
- COL15A1 | c.1921T>C p.F641L | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV66649218; called by muse, mutect2, varscan2
- COL16A1 | c.2480G>T p.G827V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54713796; called by muse, mutect2, varscan2
- COL17A1 | c.2158C>A p.L720I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as COSV62229401; called by muse, mutect2, varscan2
- COL5A1 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs138259992; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.7192G>A p.V2398I | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.384); catalogued as rs375640580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A3 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs772818200, COSV53899126; called by muse, mutect2, varscan2
- COLGALT2 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 72/372 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.908); catalogued as rs150214481; called by muse, mutect2, varscan2
- COPRS | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 42/570 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV55575647; called by muse, mutect2
- COQ8A | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371269974; called by muse, mutect2, varscan2
- COX10 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs368724576; called by muse, mutect2, varscan2
- COX15 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV50011962, COSV50013237; called by muse, varscan2
- COX15 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs779258920, COSV50013250; called by muse, mutect2, varscan2
- COX6B1 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV55838585; called by muse, varscan2
- CPB2 | c.150+2T>C p.X50_splice | Splice Site (SNP) | VAF 18/93 reads (19%) | catalogued as COSV51677444; called by muse, mutect2, varscan2
- CPED1 | c.1845G>C p.K615N | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as COSV60013161; called by muse, mutect2
- CPNE6 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV53746538; called by muse, mutect2
- CRACD | c.501del p.K167Nfs*82 | Frame Shift Del (DEL) | VAF 30/153 reads (20%) | catalogued as rs1180697484, COSV99950174; called by mutect2, varscan2
- CRHR1 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs779739917, COSV53276821; called by muse, mutect2, varscan2
- CSF1R | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV53843216; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1048A>G p.S350G | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59983439; called by muse, mutect2, varscan2
- CSMD1 | c.2690C>A p.T897N (on ENST00000520002; = p.T896N on NM_033225.6) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100144568, COSV59383150; called by muse, mutect2
- CSMD2 | c.7514G>T p.S2505I | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV53963090; called by muse, mutect2, varscan2
- CSPG4 | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57901220; called by muse, mutect2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 32/194 reads (16%) | catalogued as rs767756120; called by mutect2, varscan2
- CTDP1 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340190381, COSV50005733; called by muse, mutect2, varscan2
- CUL9 | c.5650G>A p.G1884R | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV52734707; called by muse, mutect2, varscan2
- CWF19L2 | c.977del p.N326Ifs*19 | Frame Shift Del (DEL) | VAF 17/117 reads (15%) | catalogued as COSV56519025; called by mutect2, pindel, varscan2
- CX3CR1 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV64195353; called by muse, mutect2
- CYC1 | c.304_306del p.L102del | In Frame Del (DEL) | VAF 15/106 reads (14%) | catalogued as rs754110346; called by pindel, varscan2
- CYLC2 | c.417del p.D140Ifs*8 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs761873747; called by mutect2, pindel, varscan2
- CYP11B1 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs375892072, CM1511259; called by muse, mutect2, varscan2
- CYP2E1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs749979006, COSV53315406; called by muse, mutect2, varscan2
- DAG1 | c.149T>C p.M50T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV58187200; called by muse, mutect2, varscan2
- DAPL1 | c.127del p.T43Qfs*21 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs763165810; called by mutect2, pindel, varscan2
- DCAF4L1 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV60788630; called by muse, mutect2, varscan2
- DCAF4L2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs865992251, COSV60477474, COSV60477956; called by muse, mutect2
- DCHS1 | c.6977G>A p.R2326H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as rs770087732, COSV55042768; called by muse, mutect2, varscan2
- DCLK2 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1436081098, COSV56200006, COSV56213339; called by muse, mutect2
- DDN | c.1444del p.V482* | Frame Shift Del (DEL) | VAF 9/89 reads (10%) | catalogued as rs1332841583; called by mutect2, pindel
- DDX52 | c.268del p.R90Gfs*4 | Frame Shift Del (DEL) | VAF 48/302 reads (16%) | catalogued as rs1482330308; called by mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 22/113 reads (19%) | catalogued as rs778036194; called by mutect2, varscan2
- DENND2B | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV58207792; called by muse, mutect2, varscan2
- DENND4C | c.3879T>G p.S1293R (on ENST00000434457 / NM_001330640.2; = p.S1244R on NM_017925.7) | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63009905; called by muse, mutect2, varscan2
- DENND5A | c.1354A>G p.I452V | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs758697964, COSV60237885; called by muse, mutect2, varscan2
- DGKI | c.1426-2A>G p.X476_splice | Splice Site (SNP) | VAF 20/118 reads (17%) | catalogued as COSV55975884; called by muse, mutect2, varscan2
- DHX34 | c.3064dup p.H1022Pfs*24 | Frame Shift Ins (INS) | VAF 11/68 reads (16%) | catalogued as rs760422732; called by mutect2, pindel, varscan2
- DHX35 | c.1347+1G>A p.X449_splice | Splice Site (SNP) | VAF 18/86 reads (21%) | catalogued as COSV52674504; called by muse, mutect2, varscan2
- DHX38 | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs751768845, COSV51699597; called by muse, mutect2, varscan2
- DIP2B | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV56592021; called by muse, mutect2, varscan2
- DIPK2B | c.427C>A p.R143S | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as rs945106817, COSV65005746, COSV65005879; called by muse, mutect2, varscan2
- DKK1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138015066; called by muse, mutect2, varscan2
- DLGAP3 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs778851121, COSV52394947; called by muse, mutect2, varscan2
- DMAC1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs1177257301, COSV64066097; called by muse, mutect2, varscan2
- DMD | c.10868G>A p.S3623N | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as rs1228308814, COSV58952945; called by muse, mutect2, varscan2
- DNAH3 | c.10301G>A p.G3434D | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54551507; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | catalogued as rs761292636; called by mutect2, varscan2
- DOCK9 | c.3526G>A p.V1176I (on ENST00000376460 / NM_001366676.2; = p.V1177I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as rs1471236386, COSV59643438; called by muse, mutect2
- DOK4 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as rs950033864, COSV54674352; called by muse, mutect2, varscan2
- DOLPP1 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867549099, COSV59910113; called by muse, mutect2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 30/164 reads (18%) | catalogued as rs35482889; called by mutect2, varscan2
- DPP6 | c.561A>T p.L187F (on ENST00000377770 / NM_001364500.2; = p.L125F on NM_001936.5) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.1); catalogued as COSV59645402; called by muse, mutect2, varscan2
- DPY19L2 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.033); catalogued as COSV60545973; called by muse, mutect2, varscan2
- DPYD | c.544dup p.M182Nfs*3 | Frame Shift Ins (INS) | VAF 55/319 reads (17%) | catalogued as rs754785410; called by mutect2, pindel, varscan2
- DRD4 | c.1254C>G p.C418W | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV51563410; called by muse, mutect2
- DROSHA | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs200906186, COSV60782715; called by muse, mutect2, varscan2
- DSPP | c.257C>A p.A86E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV99218015; called by muse, mutect2, varscan2
- DST | c.17189C>T p.A5730V (on ENST00000361203 / NM_001374722.1; = p.A3427V on NM_015548.5) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV55039792; called by muse, mutect2, varscan2
- DTX3 | c.329del p.G110Vfs*86 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs1288891994; called by mutect2, pindel
- DUOX2 | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV66534663; called by muse, mutect2, varscan2
- DUS1L | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV57651390; called by muse, mutect2, varscan2
- DUSP16 | c.1981A>C p.I661L | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV53809818; called by muse, mutect2, varscan2
- DYNC1I2 | c.923A>C p.E308A | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV55529766; called by muse, mutect2, varscan2
- EDIL3 | c.932T>G p.L311R | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56879439; called by muse, mutect2, varscan2
- EGFL8 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs754952287, COSV61248695; called by muse, mutect2
- EIF2AK2 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 31/142 reads (22%) | catalogued as rs191011347, COSV51799352; called by muse, mutect2, varscan2
- EIF2AK3 | c.1745dup p.N582Kfs*11 | Frame Shift Ins (INS) | VAF 57/303 reads (19%) | catalogued as rs776056726; called by mutect2, pindel, varscan2
- EIF2AK4 | c.3923A>G p.K1308R | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55474129; called by muse, mutect2, varscan2
- ELMO3 | c.1274T>C p.L425S (on ENST00000652269; = p.L372S on NM_024712.5) | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as COSV62607739; called by muse, mutect2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 45/214 reads (21%) | catalogued as rs766700925; called by mutect2, varscan2
- ELOC | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV53024162; called by muse, mutect2, varscan2
- ENPEP | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs534876489, COSV54454922; called by muse, mutect2, varscan2
- ENTPD4 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV62270264; called by muse, mutect2
- EPB41L3 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59467889; called by muse, mutect2, varscan2
- EPHB6 | c.2948A>G p.Q983R | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV63893647; called by muse, mutect2, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 36/175 reads (21%) | catalogued as rs756461692; called by mutect2, varscan2
- ERBIN | c.789T>G p.N263K | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52311962, COSV52327037; called by muse, mutect2
- ERCC6 | c.4228G>A p.G1410R | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.091); catalogued as rs4253229; called by muse, mutect2, varscan2
- ERF | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1233632467, COSV55896484; called by muse, varscan2
- ERF | c.1430G>A p.C477Y | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV55897461; called by muse, varscan2
- ERICH6 | c.1441C>A p.L481I | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as COSV55803294; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 17/140 reads (12%) | catalogued as rs753821453; called by mutect2, varscan2
- ESAM | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.91); catalogued as rs371439555; called by muse, mutect2
- ESCO2 | c.128del p.N43Mfs*15 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as COSV59416233; called by mutect2, pindel, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | catalogued as rs775950025; called by mutect2, varscan2
- ESRRG | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV63181521; called by muse, mutect2, varscan2
- ESS2 | c.1021G>A p.G341S | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767457150, COSV52818875; called by muse, mutect2, varscan2
- ETNPPL | c.486dup p.E163Rfs*17 | Frame Shift Ins (INS) | VAF 22/159 reads (14%) | catalogued as rs1194314934; called by pindel, varscan2
- EVC | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as rs141820870; called by muse, mutect2, varscan2
- EVC | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs748620929, COSV53838102; called by muse, mutect2, varscan2
- EVI5 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as rs1213431324, COSV64830205; called by muse, mutect2, varscan2
- EXOC1 | c.2259dup p.E754Rfs*23 | Frame Shift Ins (INS) | VAF 37/166 reads (22%) | catalogued as rs961507271; called by mutect2, varscan2
- EXOC2 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 35/339 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV57871910; called by muse, mutect2, varscan2
- EXOSC9 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs766182811, COSV54667952; called by muse, mutect2, varscan2
- EXT1 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as rs371817652; called by muse, mutect2, varscan2
- F10 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs745764165, COSV65022629; called by muse, mutect2, varscan2
- FAAP100 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs367556392; called by muse, mutect2, varscan2
- FAM114A1 | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62674918; called by muse, varscan2
- FAM114A2 | c.1058_1060del p.E353del | In Frame Del (DEL) | VAF 48/342 reads (14%) | catalogued as rs752924100; called by pindel, varscan2
- FAM126A | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69017654; called by muse, mutect2, varscan2
- FAM171A1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as rs775234345, COSV65320148; called by muse, mutect2, varscan2
- FAM172A | c.253A>C p.N85H | Missense Mutation (SNP) | VAF 44/329 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67942054; called by muse, mutect2, varscan2
- FAM71C | c.408del p.K136Nfs*5 | Frame Shift Del (DEL) | VAF 23/130 reads (18%) | catalogued as rs762930877; called by mutect2, pindel, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | catalogued as rs746983128; called by mutect2, varscan2
- FAR1 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs757619252, COSV61386460; called by muse, mutect2, varscan2
- FARSB | c.326T>G p.I109S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV56052592; called by muse, varscan2
- FAT3 | c.6074A>C p.K2025T | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV53148006, COSV99035557; called by muse, mutect2, varscan2
- FAT3 | c.11027C>T p.A3676V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.039); catalogued as COSV53173927; called by muse, mutect2, varscan2
- FAT4 | c.5368G>A p.D1790N | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1355201507, COSV58677218; called by muse, varscan2
- FBF1 | c.1238T>C p.L413P (on ENST00000586717; = p.L427P on NM_001319193.1) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs1163773669, COSV59867064; called by muse, mutect2
- FBLN1 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV59941978; called by muse, mutect2, varscan2
- FBN2 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV52545065; called by muse, mutect2, varscan2
- FBXO38 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.146); catalogued as rs369833842, COSV57031450; called by muse, mutect2, varscan2
- FER1L5 | c.4793T>C p.V1598A (on ENST00000623019; = p.V1571A on NM_001293083.2) | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV67607074; called by muse, mutect2
- FGD3 | c.1553C>G p.A518G | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100490447, COSV61600028; called by muse, mutect2
- FGD6 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.051); catalogued as rs754288500, COSV59694648; called by muse, mutect2, varscan2
- FGFRL1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99294867; called by muse, varscan2
- FIBCD1 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs143570837; called by muse, mutect2, varscan2
- FLNC | c.2824G>A p.V942M | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57964982; called by muse, mutect2
- FN1 | c.3491C>T p.A1164V | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs183891852; called by muse, varscan2
- FNBP4 | c.2087T>G p.L696R | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV55452226; called by muse, mutect2, varscan2
- FOCAD | c.2791del p.S931Afs*11 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs776730128; called by mutect2, pindel, varscan2
- FOCAD | c.4976C>T p.T1659I | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV58107703; called by muse, mutect2, varscan2
- FOLH1 | c.1366A>G p.I456V | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1308560052, COSV57056685; called by muse, mutect2
- FOXF1 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52288636; called by muse, mutect2
- FOXG1 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57399625; called by muse, mutect2, varscan2
- FOXO3 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs1207616793, COSV59629397; called by muse, varscan2
- FRAT1 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV64017549; called by muse, mutect2, varscan2
- FRG2B | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as rs750801693, COSV71044162; called by muse, varscan2
- FRMD6 | c.1094G>T p.R365L (on ENST00000344768 / NM_001267046.2; = p.R357L on NM_152330.4) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.598); catalogued as rs542106517, COSV61089532, COSV61090768; called by muse, mutect2, varscan2
- FRY | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV66565996, COSV66574191; called by muse, mutect2, varscan2
- FSCN3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs375234200, COSV50001153; called by muse, mutect2, varscan2
- FSD2 | c.1872G>T p.W624C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58009766, COSV58013057; called by muse, mutect2, varscan2
- FSIP2 | c.19584del p.K6528Nfs*5 | Frame Shift Del (DEL) | VAF 21/140 reads (15%) | catalogued as rs781034813; called by mutect2, pindel, varscan2
- FSTL3 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs923286991, COSV51262023; called by muse, mutect2, varscan2
- GAB4 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 65/326 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68753204; called by muse, mutect2, varscan2
- GABRA3 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100942437, COSV64805328; called by muse, mutect2, varscan2
- GALNT16 | c.956dup p.E320Rfs*4 | Frame Shift Ins (INS) | VAF 19/136 reads (14%) | catalogued as rs763094427; called by mutect2, varscan2
- GALNT17 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 104/477 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776371191, COSV61147970; called by muse, mutect2, varscan2
- GAS6 | c.449del p.G150Afs*49 | Frame Shift Del (DEL) | VAF 24/130 reads (18%) | catalogued as rs773341392; called by mutect2, pindel, varscan2
- GBP1 | c.645del p.D216Mfs*51 | Frame Shift Del (DEL) | VAF 83/506 reads (16%) | catalogued as COSV65084380; called by mutect2, pindel, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 42/270 reads (16%) | catalogued as rs754177800; called by mutect2, varscan2
- GCA | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV52026824; called by muse, mutect2, varscan2
- GCC1 | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1477328488, COSV58463827; called by muse, mutect2, varscan2
- GDF2 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs201972913; called by muse, mutect2, varscan2
- GDF5 | c.297del p.R100Dfs*23 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | catalogued as COSV65500861; called by mutect2, pindel, varscan2
- GGT1 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs199703506, COSV50638252; called by mutect2, varscan2
- GIGYF1 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765293929, COSV51946770; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | catalogued as rs750227570; called by mutect2, varscan2
- GJA1 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56999632; called by muse, mutect2, varscan2
- GLB1L2 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV60280621; called by muse, mutect2, varscan2
- GLCE | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs377258384; called by muse, mutect2, varscan2
- GLI3 | c.3677C>A p.P1226Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.001); catalogued as COSV67894966; called by muse, mutect2, varscan2
- GLIS3 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368943263; called by muse, mutect2, varscan2
- GNB1L | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs765685532, COSV61547693; called by muse, mutect2, varscan2
- GOLGA4 | c.75G>A p.A25= | Splice Region (SNP) | VAF 10/102 reads (10%) | catalogued as rs201354584, COSV62709319, COSV62710637; called by muse, mutect2, varscan2
- GOLGB1 | c.6839A>G p.D2280G | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.204); catalogued as COSV61470979; called by muse, mutect2
- GPA33 | c.781T>C p.C261R | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs1235661955, COSV63300965; called by muse, mutect2, varscan2
- GPBP1 | c.975T>C p.D325= | Splice Region (SNP) | VAF 20/112 reads (18%) | catalogued as COSV53314654; called by muse, mutect2, varscan2
- GPC5 | c.776C>A p.P259Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65630065; called by muse, mutect2, varscan2
- GPER1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.144); catalogued as rs564861434, COSV52470640; called by mutect2, varscan2
- GPHA2 | c.242_244del p.N81del | In Frame Del (DEL) | VAF 26/165 reads (16%) | catalogued as rs770756859; called by pindel, varscan2
- GPR137 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1297605041, COSV57402264; called by muse, mutect2
- GPR161 | c.1513A>G p.S505G | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); catalogued as COSV54794672; called by muse, mutect2
- GPR82 | c.875del p.N292Tfs*21 | Frame Shift Del (DEL) | VAF 31/135 reads (23%) | catalogued as rs1158686199, COSV56886767; called by mutect2, pindel, varscan2
- GRIA1 | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53624601; called by muse, mutect2
- GRIA1 | c.1551G>A p.M517I | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV53624624; called by muse, mutect2, varscan2
- GRIA1 | c.2005A>G p.T669A | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53624645; called by muse, mutect2, varscan2
- GRIK5 | c.1933G>A p.V645M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555872788, COSV53474359; called by muse, mutect2
- GRIN3B | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); catalogued as rs749404495, COSV52263535; called by muse, mutect2
- GRINA | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.082); catalogued as rs1457122728, COSV57592601; called by muse, mutect2, varscan2
- GRIP1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs746032734, COSV54042981; called by muse, mutect2, varscan2
- GRM1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51121413, COSV51322349; called by muse, mutect2, varscan2
- GRM6 | c.2545C>T p.Q849* | Nonsense Mutation (SNP) | VAF 34/196 reads (17%) | catalogued as COSV51449511; called by muse, mutect2, varscan2
- GSX2 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58843526; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2378T>C p.L793P | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100441284; called by muse, mutect2, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | catalogued as rs750792116; called by mutect2, varscan2
- GTF3C4 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64646140; called by muse, mutect2, varscan2
- GUCY2C | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1350457969, COSV53795592; called by muse, varscan2
- GUCY2C | c.2056C>T p.R686W | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs192199843, COSV53795600; called by muse, mutect2, varscan2
- GUCY2C | c.1928del p.K643Rfs*41 | Frame Shift Del (DEL) | VAF 25/241 reads (10%) | catalogued as COSV53786951; called by mutect2, pindel, varscan2
- H3C13 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as rs1285610295, COSV58944922; called by muse, mutect2, varscan2
- HABP4 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100928276; called by muse, mutect2, varscan2
- HDAC10 | c.1055C>A p.P352Q | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV50558117, COSV50584690; called by muse, mutect2, varscan2
- HDAC3 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51838690; called by muse, mutect2
- HEATR9 | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 63/347 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs371570312; called by muse, mutect2, varscan2
- HECA | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as rs1408349298, COSV100866261; called by muse, mutect2, varscan2
- HECTD4 | c.13100dup p.D4368Rfs*44 | Frame Shift Ins (INS) | VAF 21/154 reads (14%) | catalogued as rs746492036; called by mutect2, varscan2
- HGSNAT | c.1420C>A p.L474M | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52817298; called by muse, mutect2, varscan2
- HHAT | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 85/411 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV54809829, COSV99803504; called by muse, mutect2, varscan2
- HHATL | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs762289236, COSV60043137; called by muse, mutect2, varscan2
- HIC2 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.077); catalogued as rs1010826578, COSV68042887; called by muse, mutect2
- HIPK2 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756724364, COSV100702108, COSV61232676; called by muse, mutect2, varscan2
- HKDC1 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as rs537386563, COSV63579347; called by muse, mutect2, varscan2
- HLA-B | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.791); catalogued as rs756666358, COSV69522171; called by muse, mutect2, varscan2
- HMBOX1 | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV55072064; called by muse, mutect2
- HMCN1 | c.14345G>A p.R4782H | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758569536, COSV54904411; called by muse, mutect2, varscan2
- HNF4G | c.98A>C p.K33T (on ENST00000354370 / NM_001330561.2; = p.K80T on NM_004133.5) | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62973679; called by muse, mutect2, varscan2
- HOOK3 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs1434647860, COSV56887853; called by muse, mutect2, varscan2
- HOXC10 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs780462718, COSV57727095; called by muse, mutect2, varscan2
- HOXC13 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747385249, COSV54498111; called by muse, mutect2, varscan2
- HOXC5 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV54538247; called by muse, mutect2
- HS3ST5 | c.378del p.F126Lfs*47 | Frame Shift Del (DEL) | VAF 60/292 reads (21%) | catalogued as rs1378538840; called by mutect2, pindel, varscan2
- HSD17B12 | c.785C>A p.T262K | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV53504087; called by muse, mutect2, varscan2
- HSF2BP | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52359936; called by muse, mutect2, varscan2
- HSPBAP1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.398); catalogued as COSV53745337, COSV53749661; called by muse, mutect2, varscan2
- HSPG2 | c.2302G>T p.G768C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65977282; called by muse, mutect2, varscan2
- HYAL4 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs965576294, COSV56140425; called by muse, mutect2
- IBTK | c.248_249del p.K83Rfs*17 | Frame Shift Del (DEL) | VAF 34/176 reads (19%) | catalogued as rs1396571975; called by mutect2, pindel, varscan2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs771790236; called by mutect2, varscan2
- IFIT2 | c.545G>T p.S182I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.084); catalogued as COSV51080717; called by muse, mutect2, varscan2
- IFT88 | c.2275G>A p.G759S (on ENST00000319980 / NM_001318493.2; = p.G750S on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.609); catalogued as rs138716049; called by muse, mutect2, varscan2
- IGF1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs1316717107, COSV61031712; called by muse, mutect2, varscan2
- IGF2BP1 | c.592del p.L198Ffs*32 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as COSV51736634; called by mutect2, pindel
- IGHV3-23 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 60/561 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.29); catalogued as rs781922217; called by muse, mutect2, varscan2
- IGSF3 | c.2867A>C p.D956A (on ENST00000369486 / NM_001007237.3; = p.D976A on NM_001542.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59598612; called by muse, mutect2, varscan2
- IL1RAP | c.864del p.K288Nfs*15 | Frame Shift Del (DEL) | VAF 16/131 reads (12%) | catalogued as rs780458834, COSV50762431; called by mutect2, pindel, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs745545309; called by mutect2, pindel, varscan2
- IL4I1 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs867448495, COSV62009846, COSV62012131; called by muse, mutect2
- IMPG2 | c.1424C>A p.S475Y | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV51985702; called by muse, mutect2, varscan2
- INCENP | c.2549C>T p.P850L (on ENST00000394818 / NM_001040694.2; = p.P846L on NM_020238.3) | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs781470064, COSV53913156; called by muse, mutect2
- INO80 | c.1645A>G p.K549E | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV62739531; called by muse, varscan2
- INPP5B | c.2381T>C p.M794T (on ENST00000373023; = p.M714T on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV65963077; called by muse, mutect2, varscan2
- INSRR | c.1420del p.R474Afs*20 | Frame Shift Del (DEL) | VAF 25/105 reads (24%) | catalogued as COSV63870936; called by mutect2, pindel, varscan2
- INSRR | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as rs140347940; called by muse, mutect2, varscan2
- INTS4 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs759915571, COSV101417291; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IQCN | c.2831G>A p.R944H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs200997372, COSV62748744; called by muse, varscan2
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 42/214 reads (20%) | catalogued as rs771739474; called by mutect2, varscan2
- IRGC | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.076); catalogued as rs1253740345, COSV54982674; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs761880048; called by mutect2, varscan2
- ITGB7 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs750166096, COSV57240432; called by muse, mutect2, varscan2
- ITPKA | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323392557, COSV53029305; called by muse, mutect2, varscan2
- JAK2 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67674405; called by muse, mutect2, varscan2
- JRK | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); catalogued as rs782347045, COSV70630469; called by muse, mutect2
- KALRN | c.8770C>T p.R2924W (on ENST00000360013 / NM_001024660.4; = p.R1227W on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs889918445, COSV52264595; called by muse, mutect2, varscan2
- KAT6B | c.3511C>T p.Q1171* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as COSV54754667; called by muse, mutect2
- KATNB1 | c.1643+1G>A p.X548_splice | Splice Site (SNP) | VAF 4/46 reads (9%) | catalogued as COSV65553235; called by muse, mutect2, varscan2
- KATNBL1 | c.30dup p.R11Tfs*5 | Frame Shift Ins (INS) | VAF 21/105 reads (20%) | catalogued as rs747482112; called by mutect2, pindel, varscan2
- KAZN | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs755820319, COSV63210399; called by muse, mutect2
- KBTBD12 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV59681983; called by muse, mutect2, varscan2
- KCNA1 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1053557642, COSV66836572; called by muse, mutect2, varscan2
- KCNA3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV63902597; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 44/180 reads (24%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNH3 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750261167, COSV57790761; called by muse, mutect2, varscan2
- KCNJ6 | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55723313; called by muse, mutect2
- KCNK5 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as rs757159016, COSV100851746, COSV63989432; called by muse, mutect2, varscan2
- KCNK7 | c.914del p.P305Lfs*? | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as COSV100442405; called by mutect2, pindel, varscan2
- KCNQ4 | c.291G>T p.W97C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100714385; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 36/146 reads (25%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KDM2B | c.127-2A>G p.X43_splice | Splice Site (SNP) | VAF 10/94 reads (11%) | catalogued as COSV65645151; called by muse, mutect2
- KDM3B | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58695335; called by muse, mutect2, varscan2
- KDM4B | c.586T>C p.Y196H | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50262169; called by muse, mutect2, varscan2
- KHDRBS1 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs998460178, COSV56983744; called by muse, mutect2
- KHDRBS2 | c.131A>T p.D44V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.221); catalogued as COSV55492090; called by muse, mutect2, varscan2
- KIAA0232 | c.2710T>A p.S904T | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV56929482; called by muse, mutect2, varscan2
- KIAA1109 | c.5873G>A p.R1958Q | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1263871665, COSV52664246; called by muse, mutect2, varscan2
- KIAA1217 | c.1487del p.P496Lfs*26 | Frame Shift Del (DEL) | VAF 11/99 reads (11%) | catalogued as COSV56813511; called by mutect2, pindel, varscan2
- KIAA1614 | c.1794_1795del p.I599Rfs*20 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs779525951; called by pindel, varscan2
- KIF20B | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as rs1050818241, COSV53306948; called by muse, mutect2, varscan2
- KIF24 | c.1367A>G p.E456G | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61458080; called by muse, varscan2
- KIF27 | c.3652C>T p.R1218W | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376993923, COSV52831217; called by muse, mutect2, varscan2
- KIF3B | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs748063389, COSV65229342; called by muse, mutect2, varscan2
- KIF3B | c.1131G>T p.R377S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV65229348; called by muse, mutect2, varscan2
- KIF4B | c.2966T>C p.I989T | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV70531351; called by muse, mutect2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 31/183 reads (17%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KIRREL1 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751855855, COSV100779267, COSV63291404; called by muse, mutect2, varscan2
- KLF10 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as rs759489236, COSV53435890; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 64/318 reads (20%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHDC8B | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60412347; called by muse, mutect2, varscan2
- KLHL42 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs752729834, COSV67146238; called by muse, mutect2, varscan2
- KLK13 | c.563A>G p.E188G | Missense Mutation (SNP) | VAF 80/357 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV50067592; called by muse, mutect2, varscan2
- KMT2A | c.10834G>A p.A3612T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV63292503; called by muse, mutect2, varscan2
- KPNA2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 96/516 reads (19%) | catalogued as rs1266467492, COSV57857239; called by muse, mutect2, varscan2
- KRT3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs530962648, COSV58817332; called by muse, mutect2, varscan2
- KRT32 | c.58del p.R20Gfs*10 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as COSV99863174; called by mutect2, pindel, varscan2
- KRTAP3-3 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV66956815; called by muse, mutect2, varscan2
- LAD1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs201317042, COSV66213334; called by muse, mutect2, varscan2
- LAMA1 | c.1487del p.N496Tfs*27 | Frame Shift Del (DEL) | VAF 36/238 reads (15%) | catalogued as rs1406609727; called by mutect2, varscan2
- LAMA2 | c.7963A>G p.I2655V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs775415222, COSV70355082; called by muse, mutect2, varscan2
- LAMB3 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV61919699; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LAS1L | c.524T>C p.F175S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV56709024; called by muse, mutect2, varscan2
- LAT2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1554715731, COSV51921825; called by muse, varscan2
- LBX1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs774344628, COSV64622152; called by muse, mutect2, varscan2
- LDB2 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 10/172 reads (6%) | catalogued as COSV58782749; called by muse, mutect2
- LGI1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV65058853; called by muse, mutect2, varscan2
- LHFPL5 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as COSV64178750; called by muse, mutect2, varscan2
- LHX4 | c.964T>C p.S322P | Missense Mutation (SNP) | VAF 92/419 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1446081218, COSV55378166; called by muse, mutect2, varscan2
- LIMCH1 | c.3110T>C p.I1037T | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58283768, COSV58297018; called by muse, mutect2, varscan2
- LRCH3 | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58396822; called by muse, mutect2, varscan2
- LRP1 | c.3241C>T p.R1081C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs761523540, COSV54513881, COSV54515328; called by muse, mutect2, varscan2
- LRP1 | c.4468dup p.E1490Gfs*6 | Frame Shift Ins (INS) | VAF 18/122 reads (15%) | catalogued as rs139915490; called by mutect2, varscan2
- LRP2 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs763860226, COSV55542058; called by muse, mutect2, varscan2
- LRRC14 | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99467561, COSV99468274; called by muse, mutect2
- LRRC4B | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65350301; called by muse, mutect2, varscan2
- LRRC75A | c.256A>G p.M86V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV69126488; called by muse, mutect2, varscan2
- LRRFIP2 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV60870333; called by muse, mutect2
- LRRK2 | c.5609T>C p.L1870S | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV54170511; called by muse, mutect2, varscan2
- LRRN4 | c.2012G>A p.C671Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66646498; called by muse, mutect2
- LRRN4CL | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV54017811; called by muse, mutect2, varscan2
- LTBP2 | c.4918C>T p.R1640C | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs760591150, COSV56214133; called by muse, mutect2, varscan2
- LTF | c.1681G>A p.V561I | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762422805, COSV51612114; called by muse, mutect2, varscan2
- LTO1 | c.134A>G p.H45R | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs985594243, COSV54163599; called by muse, mutect2, varscan2
- LY75 | c.4235del p.K1412Rfs*2 | Frame Shift Del (DEL) | VAF 17/123 reads (14%) | catalogued as rs1301982151; called by mutect2, varscan2
- LY75 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55113095; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 34/162 reads (21%) | catalogued as rs752439249; called by mutect2, varscan2
- MAG | c.758A>T p.E253V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62702885; called by muse, mutect2
- MAGED1 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.028); catalogued as COSV58516901; called by muse, mutect2, varscan2
- MAK | c.855A>C p.Q285H | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.152); catalogued as COSV57567760; called by muse, mutect2, varscan2
- MAML1 | c.2885C>A p.P962H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as COSV52988751; called by muse, mutect2, varscan2
- MAP3K3 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV62281788; called by muse, mutect2, varscan2
- MAP6 | c.1852G>T p.G618C | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV59077903; called by muse, mutect2, varscan2
- MAPK15 | c.1538del p.G513Vfs*? | Frame Shift Del (DEL) | VAF 27/188 reads (14%) | catalogued as rs782558070; called by mutect2, pindel, varscan2
- MARK2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59289084; called by muse, mutect2
- MARK2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as rs973521004, COSV59288594, COSV59289098; called by muse, mutect2, varscan2
- MAST2 | c.2992G>T p.A998S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.024); catalogued as COSV63621459; called by muse, mutect2, varscan2
- MAVS | c.1405C>A p.H469N | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV63927614; called by muse, mutect2, varscan2
- MBD5 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV68698945; called by muse, mutect2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 41/251 reads (16%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MBIP | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs758726043, COSV59255281; called by muse, mutect2, varscan2
- MCF2L | c.2463C>T p.D821= (on ENST00000375608; = p.D789= on NM_024979.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 6/82 reads (7%) | catalogued as rs947895738, COSV56181476; called by muse, mutect2
- MCF2L2 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs368970289; called by muse, mutect2, varscan2
- MCMBP | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV63510669; called by muse, mutect2, varscan2
- MDC1 | c.3289G>T p.E1097* | Nonsense Mutation (SNP) | VAF 80/400 reads (20%) | catalogued as COSV64527631; called by muse, mutect2, varscan2
- MDM4 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.868); catalogued as rs966981669, COSV65795025; called by muse, mutect2, varscan2
- MED15 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV53033501; called by muse, mutect2
- MED26 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.151); catalogued as rs575658283, COSV54663050, COSV99660047; called by muse, mutect2, varscan2
- MEGF8 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746105455, COSV52078555, COSV52101636; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 23/120 reads (19%) | catalogued as rs745891632; called by mutect2, varscan2
- METAP1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs571036181, COSV56446082; called by muse, mutect2, varscan2
- MFSD1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs753535023, COSV51843367; called by muse, mutect2, varscan2
- MIB2 | c.2258T>C p.L753P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61543465; called by muse, mutect2, varscan2
- MICU1 | c.1181T>C p.V394A (on ENST00000361114 / NM_001195518.2; = p.V400A on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63147780; called by muse, mutect2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs762448666; called by pindel, varscan2
- MINDY1 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587720999, COSV56500839; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 46/262 reads (18%) | catalogued as rs751465048; called by mutect2, varscan2
- MMACHC | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs763226016, COSV53115049; called by muse, mutect2, varscan2
- MMP9 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755934245, COSV63434478; called by muse, mutect2, varscan2
- MMRN1 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV53342753; called by muse, mutect2, varscan2
- MOCOS | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV54341125; called by muse, mutect2, varscan2
- MPDZ | c.1118G>T p.S373I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59951006; called by muse, mutect2, varscan2
- MPP3 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV68199255; called by muse, mutect2, varscan2
- MR1 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51582239; called by muse, mutect2, varscan2
- MRFAP1L1 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.775); catalogued as COSV57923323; called by muse, mutect2, varscan2
- MSANTD4 | c.561del p.F187Lfs*19 | Frame Shift Del (DEL) | VAF 42/222 reads (19%) | catalogued as rs1475601536; called by mutect2, pindel, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as rs759847587; called by mutect2, varscan2
- MTUS1 | c.3776C>T p.S1259L (on ENST00000262102 / NM_001363061.1; = p.S425L on NM_020749.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148435996, COSV50590541; called by muse, mutect2, varscan2
- MUC16 | c.31664G>T p.R10555M | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.235); catalogued as COSV67442697, COSV67494147; called by muse, mutect2
- MUC16 | c.8168A>G p.H2723R | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV67494149; called by muse, mutect2, varscan2
- MYBPC2 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as rs144074433, COSV63099912; called by muse, mutect2, varscan2
- MYH6 | c.3575C>T p.A1192V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs765797952, COSV100676803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs199637885, COSV100806694; called by mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 26/134 reads (19%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO15A | c.9251A>G p.D3084G | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375166246; called by muse, mutect2, varscan2
- MYO1D | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1366755677, COSV59006869; called by muse, mutect2
- MYO3A | c.3574dup p.M1192Nfs*3 | Frame Shift Ins (INS) | VAF 24/100 reads (24%) | catalogued as rs757810767; called by mutect2, varscan2
- MYORG | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs536187898, COSV52628357; ClinVar: uncertain significance; called by muse, mutect2
- MYRIP | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs764972670, COSV56867019; called by muse, mutect2, varscan2
- NAA15 | c.1015-1G>T p.X339_splice | Splice Site (SNP) | VAF 44/183 reads (24%) | catalogued as COSV56722689; called by muse, mutect2, varscan2
- NAAA | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746051493, COSV54432094; called by muse, mutect2
- NAALADL1 | c.146T>C p.M49T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs760168319, COSV60523978; called by muse, mutect2, varscan2
- NAPB | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV65465280; called by muse, mutect2, varscan2
- NAV2 | c.4921G>A p.V1641M | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV60665362; called by muse, mutect2, varscan2
- NAV3 | c.4988G>A p.R1663H | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs368252063; called by muse, mutect2, varscan2
- NBEAL1 | c.6508+1G>A p.X2170_splice | Splice Site (SNP) | VAF 15/71 reads (21%) | catalogued as rs371479430; called by muse, mutect2
- NCKAP5L | c.633del p.W212Gfs*35 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs35391945; called by mutect2, pindel, varscan2
- NCOA1 | c.3716C>T p.P1239L | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as COSV56039300; called by muse, mutect2, varscan2
- NCOA6 | c.2042A>G p.K681R | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62868052; called by muse, mutect2, varscan2
- NCOA6 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as rs753265917, COSV62868056; called by muse, mutect2, varscan2
- NCOA7 | c.209del p.K70Rfs*7 | Frame Shift Del (DEL) | VAF 42/253 reads (17%) | catalogued as rs749319230; called by mutect2, varscan2
- NDN | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs1338477724, COSV59358349; called by muse, mutect2, varscan2
- NDRG4 | c.88C>T p.R30C (on ENST00000570248 / NM_001378344.1; = p.R62C on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs202237732; called by muse, mutect2, varscan2
- NEDD4 | c.3004T>A p.L1002M (on ENST00000508342 / NM_001284338.1; = p.L583M on NM_006154.4) | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59066646; called by muse, mutect2
- NES | c.2366A>C p.K789T | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV63962928; called by muse, mutect2, varscan2
- NFAT5 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 24/117 reads (21%) | catalogued as COSV63032700; called by muse, mutect2, varscan2
- NFATC1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.242); catalogued as rs773868340, COSV53709390; called by muse, mutect2, varscan2
- NFKBIL1 | c.19dup p.Q7Pfs*84 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | catalogued as rs1376248551; called by mutect2, pindel
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 27/152 reads (18%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NGFR | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV50801853; called by muse, mutect2, varscan2
- NIPA1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61680737; called by muse, mutect2, varscan2
- NIPA1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV61680732; called by muse, mutect2
- NIPA1 | c.962T>C p.M321T | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV61680728; called by muse, mutect2, varscan2
- NKTR | c.1183A>T p.S395C | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV99236401; called by muse, mutect2, varscan2
- NLGN4X | c.753T>G p.F251L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV52036466; called by muse, mutect2, varscan2
- NME1-NME2 | c.667G>A p.V223M (on ENST00000555572; = p.V198M on NM_001018136.3) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs757730632, COSV64510992; called by muse, mutect2, varscan2
- NME8 | c.507dup p.V170Sfs*5 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | catalogued as rs1167912395; called by mutect2, pindel
- NMRK1 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV63112981; called by muse, mutect2, varscan2
- NOMO3 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as rs770035084, COSV99530970; called by muse, mutect2, varscan2
- NOTCH1 | c.2348T>C p.F783S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53094161; called by muse, varscan2
- NOTCH2 | c.4888C>T p.R1630C | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56687234, COSV56701592; called by muse, mutect2, varscan2
- NPM2 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57076617; called by muse, mutect2, varscan2
- NR2C1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58012321; called by muse, mutect2, varscan2
- NR6A1 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.094); catalogued as rs1440110288, COSV60637853; called by muse, mutect2, varscan2
- NRIP1 | c.2948G>A p.G983E | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.387); catalogued as COSV59660354; called by muse, mutect2, varscan2
- NRXN3 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as rs748519678, COSV73587361; called by muse, mutect2, varscan2
- NSMAF | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs371510352; called by muse, mutect2, varscan2
- NSMF | c.1337G>A p.R446H (on ENST00000371475 / NM_001130969.3; = p.R444H on NM_015537.4) | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs1384701847, COSV55811101; called by muse, mutect2, varscan2
- NTNG2 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100647768; called by muse, mutect2
- NUP155 | c.755G>A p.R252K (on ENST00000231498 / NM_153485.3; = p.R193K on NM_004298.4) | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as COSV51534788; called by muse, mutect2
- NUP210L | c.2512A>G p.M838V | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV55157723; called by muse, mutect2, varscan2
- NXPE3 | c.1532G>A p.R511K | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV56292283; called by muse, mutect2, varscan2
- OBSCN | c.7222C>T p.R2408W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs775749451, COSV52747557; called by muse, mutect2, varscan2
- OGFOD1 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV55860796; called by muse, mutect2
- OR10AG1 | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV56634799; called by muse, mutect2, varscan2
- OR10H2 | c.533del p.L178Yfs*8 | Frame Shift Del (DEL) | VAF 33/179 reads (18%) | catalogued as COSV59946147; called by mutect2, pindel, varscan2
- OR10H2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100008660, COSV59947085; called by muse, mutect2
- OR10W1 | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs745742757, COSV67720865; called by muse, mutect2, varscan2
- OR1L8 | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs1564200120, COSV59187436; called by muse, mutect2, varscan2
- OR2M4 | c.528del p.F178Sfs*28 | Frame Shift Del (DEL) | VAF 60/336 reads (18%) | catalogued as rs1331956668; called by mutect2, pindel, varscan2
- OR4C16 | c.89del p.L30Cfs*13 | Frame Shift Del (DEL) | VAF 38/273 reads (14%) | catalogued as rs752324980; called by mutect2, pindel, varscan2
- OR51B4 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV66517821; called by muse, mutect2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as rs755413956; called by mutect2, varscan2
- OR6B1 | c.833T>C p.I278T | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV68770661; called by muse, mutect2, varscan2
- OR8G5 | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 63/423 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as rs773246935, COSV100422682; called by muse, mutect2, varscan2
- OR8H3 | c.221A>C p.Y74S | Missense Mutation (SNP) | VAF 115/788 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57911639; called by muse, mutect2, varscan2
- OR9K2 | c.978del p.K326Nfs*3 (on ENST00000305377; = p.K304Nfs*3 on NM_001005243.1) | Frame Shift Del (DEL) | VAF 38/173 reads (22%) | catalogued as rs1249976011; called by mutect2, pindel, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 57/279 reads (20%) | catalogued as rs751106039; called by mutect2, varscan2
- OXR1 | c.2552C>T p.T851M (on ENST00000442977 / NM_001198532.1; = p.T823M on NM_018002.3) | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459324936, COSV52427781; called by muse, mutect2
- P2RX2 | c.688G>A p.E230K (on ENST00000343948 / NM_170683.4; = p.E158K on NM_012226.5) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.239); catalogued as COSV57690588; called by muse, mutect2, varscan2
- PANK4 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs760324597, COSV65866318; called by muse, mutect2
- PAPOLA | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53485396; called by muse, mutect2
- PAPPA2 | c.195T>G p.H65Q | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); catalogued as COSV62786754; called by muse, mutect2, varscan2
- PAPPA2 | c.5055dup p.S1686Qfs*2 | Frame Shift Ins (INS) | VAF 15/101 reads (15%) | catalogued as rs747970462; called by mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs758945932; called by mutect2, varscan2
- PARP16 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56036638; called by muse, mutect2
- PARP2 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV51642113; called by muse, mutect2, varscan2
- PAX3 | c.458C>A p.S153Y | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51344651; called by muse, mutect2, varscan2
- PAX9 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1284027470, COSV64062568; called by muse, mutect2, varscan2
- PBX1 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63348258; called by muse, mutect2
- PCDH10 | c.360dup p.S121Lfs*13 | Frame Shift Ins (INS) | VAF 20/101 reads (20%) | catalogued as rs759095467; called by mutect2, varscan2
- PCDH10 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52097176, COSV99994735; called by muse, mutect2, varscan2
- PCDH11X | c.2149G>T p.G717* | Nonsense Mutation (SNP) | VAF 43/198 reads (22%) | catalogued as COSV100015469; called by muse, mutect2, varscan2
- PCDHA11 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.037); catalogued as rs180868237, COSV56545773; called by muse, mutect2, varscan2
- PCDHA4 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV63541380, COSV63542990; called by muse, mutect2, varscan2
- PCDHA6 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 82/469 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); catalogued as COSV65351995; called by muse, mutect2, varscan2
- PCDHA7 | c.1121T>C p.V374A | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV65347572; called by muse, mutect2, varscan2
- PCDHAC1 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53870009; called by muse, mutect2, varscan2
- PCDHB6 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50730777; called by muse, varscan2
- PCDHB8 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as rs1483942587, COSV50753538; called by muse, mutect2, varscan2
- PCID2 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs746816072, COSV55815130; called by muse, mutect2, varscan2
- PDE4B | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289148672, COSV58472055; called by muse, mutect2, varscan2
- PDGFB | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as rs146204796; called by muse, mutect2
- PDHB | c.820A>G p.M274V | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV57058024; called by muse, mutect2, varscan2
- PDILT | c.659A>T p.D220V | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56705262; called by muse, mutect2, varscan2
- PDZD2 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs542284593, COSV56852390, COSV99226373; called by muse, mutect2, varscan2
- PER2 | c.1757G>T p.C586F | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54527746; called by muse, mutect2, varscan2
- PEX16 | c.695T>C p.L232S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53804225; called by muse, mutect2, varscan2
- PGAM4 | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs782643568, COSV58453871; called by muse, mutect2, varscan2
- PGBD1 | c.2005dup p.M669Nfs*7 | Frame Shift Ins (INS) | VAF 34/186 reads (18%) | catalogued as rs781166611; called by mutect2, varscan2
- PHF24 | c.917del p.G306Afs*91 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as COSV54273111; called by mutect2, pindel, varscan2
- PHKA2 | c.3328A>G p.T1110A | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV66056269; called by muse, mutect2, varscan2
- PIANP | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as COSV57708494; called by muse, mutect2, varscan2
- PIAS4 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.241); catalogued as COSV53681123; called by muse, mutect2, varscan2
- PID1 | c.218C>T p.A73V (on ENST00000354069 / NM_001330156.1; = p.A71V on NM_017933.5) | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.575); catalogued as rs750696637, COSV62482846; called by muse, mutect2, varscan2
- PIGR | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs763319879, COSV62904993; called by muse, mutect2, varscan2
- PIGT | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs577271638, COSV54128860; called by muse, mutect2, varscan2
- PITPNM1 | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV62709884; called by muse, mutect2, varscan2
- PITX1 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV54761544; called by muse, mutect2, varscan2
- PKN2 | c.232del p.S78Vfs*5 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | catalogued as rs1335792632, COSV60133695; called by mutect2, pindel, varscan2
- PLEKHA5 | c.2995del p.T999Lfs*17 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs759995048, COSV54701412; called by mutect2, varscan2
- PLG | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51982901, COSV51986506; called by muse, mutect2
- PLG | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs982446880, COSV51986512; called by muse, mutect2, varscan2
- PLPP2 | c.448T>C p.C150R | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54122091; called by muse, varscan2
- PLXNA4 | c.2195C>A p.S732Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58160209; called by muse, mutect2, varscan2
- PLXNB2 | c.5401T>C p.Y1801H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779693958, COSV63784430; called by mutect2, varscan2
- PLXND1 | c.3244A>G p.S1082G | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs776923438, COSV60719391; called by muse, mutect2, varscan2
- PNMA3 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs781807597, COSV64722980; called by muse, mutect2, varscan2
- PNMA8B | c.905del p.P302Rfs*50 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | catalogued as rs1568617650, COSV66536647; called by mutect2, pindel, varscan2
- PODN | c.908del p.P303Rfs*7 (on ENST00000395871; = p.P255Rfs*7 on NM_153703.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 29/228 reads (13%) | catalogued as rs1464111568, COSV57017199; called by mutect2, pindel, varscan2
- POGLUT3 | c.1098+2T>C p.X366_splice | Splice Site (SNP) | VAF 67/275 reads (24%) | catalogued as rs901251925, COSV60214154; called by muse, mutect2, varscan2
- POLQ | c.5168G>A p.R1723H | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs748483271, COSV51757206; called by mutect2, varscan2
- POLR1A | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs552444742, COSV55697965; called by muse, mutect2, varscan2
- PPARA | c.1174C>A p.L392I | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV53081428; called by muse, mutect2, varscan2
- PPP1R10 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64740459; called by muse, mutect2, varscan2
- PPP1R1C | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54719668; called by muse, mutect2, varscan2
- PPP1R32 | c.1063A>G p.K355E | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV58546130; called by muse, mutect2
- PPP1R3A | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765161960, COSV52877395, COSV52890078; called by muse, mutect2, varscan2
- PRICKLE2 | c.1175G>A p.R392H (on ENST00000295902; = p.R336H on NM_198859.4) | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs147289291; called by muse, mutect2, varscan2
- PRIMPOL | c.884C>A p.S295* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV59250722; called by muse, mutect2, varscan2
- PRKACB | c.145del p.T49Pfs*13 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | catalogued as rs1291568884; called by mutect2, pindel, varscan2
- PRKAR2B | c.843+2T>C p.X281_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as COSV55927559; called by muse, mutect2, varscan2
- PRKCSH | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs561459049, COSV52950772; called by muse, mutect2, varscan2
- PRMT6 | c.182T>A p.I61N | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV63656504; called by muse, mutect2
- PRMT7 | c.510T>A p.N170K | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV59835722; called by muse, mutect2, varscan2
- PRODH2 | c.1399A>G p.M467V (on ENST00000301175; = p.M391V on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56562207; called by muse, mutect2, varscan2
- PRPF6 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1353057336, COSV53874500; called by muse, mutect2, varscan2
- PRRT1 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52999608; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PRUNE2 | c.5069A>G p.D1690G | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV65047970; called by muse, mutect2, varscan2
- PSAP | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs545627914, COSV56450422; called by muse, mutect2, varscan2
- PSD2 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs370549557; called by muse, mutect2, varscan2
- PSG1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs1058748, COSV54959904; called by muse, mutect2, varscan2
- PSME2 | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 46/295 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV53757721; called by muse, mutect2, varscan2
- PTAFR | c.763T>C p.W255R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59538348; called by muse, mutect2, varscan2
- PTGFR | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 9/272 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66116729; called by muse, mutect2
- PTPN7 | c.58del p.A20Qfs*3 (on ENST00000495688; = p.A59Qfs*3 on NM_002832.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as rs112539145; called by mutect2, pindel, varscan2
- PTPRD | c.3632A>G p.Y1211C | Missense Mutation (SNP) | VAF 63/281 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61981558; called by muse, mutect2, varscan2
- PTPRK | c.2806C>T p.P936S (on ENST00000368215 / NM_001291984.2; = p.P937S on NM_002844.4) | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.743); catalogued as rs1159505160, COSV63891651; called by muse, mutect2, varscan2
- PTPRM | c.3062A>G p.D1021G | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59881883; called by muse, mutect2, varscan2
- PTPRT | c.1887G>T p.K629N | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV62020615; called by muse, mutect2
- PVR | c.1127G>T p.W376L | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.991); catalogued as COSV51824769; called by muse, mutect2, varscan2
- RAB34 | c.399C>A p.N133K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV56388748; called by muse, mutect2, varscan2
- RAB38 | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 98/459 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54716138; called by muse, mutect2, varscan2
- RABAC1 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV55771356; called by muse, mutect2
- RABGAP1 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.223); catalogued as rs1017113198, COSV58061067; called by muse, mutect2, varscan2
- RANBP17 | c.2155G>A p.G719R | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199577427; called by muse, mutect2, varscan2
- RAPGEF5 | c.623T>C p.V208A (on ENST00000401957 / NM_001367602.2; = p.V511A on NM_012294.5) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as rs776916179, COSV59792023; called by muse, mutect2, varscan2
- RAPH1 | c.2294del p.P765Hfs*19 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs760908242; called by mutect2, varscan2
- RASAL2 | c.722del p.K241Rfs*7 | Frame Shift Del (DEL) | VAF 26/134 reads (19%) | catalogued as rs771909008; called by mutect2, varscan2
- RBBP6 | c.3654A>C p.K1218N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60508465; called by muse, mutect2, varscan2
- RBMS3 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1421332978, COSV56148034; called by muse, mutect2, varscan2
- RCOR3 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.69); catalogued as COSV65366890; called by muse, mutect2, varscan2
- RCVRN | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs374805649; called by muse, mutect2, varscan2
- RGL3 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV62699193; called by muse, mutect2, varscan2
- RGS10 | c.365T>C p.L122P (on ENST00000369101; = p.L116P on NM_002925.3) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV64862619; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 29/130 reads (22%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS22 | c.3376dup p.V1126Gfs*4 | Frame Shift Ins (INS) | VAF 19/108 reads (18%) | catalogued as rs35278820; called by mutect2, pindel, varscan2
- RGS3 | c.577G>A p.V193I (on ENST00000350696 / NM_001282923.2; = p.V81I on NM_017790.4) | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs770598136, COSV58285615, COSV99048032; called by muse, mutect2, varscan2
- RGS6 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs751525654, COSV100664715, COSV59579508; called by muse, mutect2, varscan2
- RHOBTB2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs757818105, COSV99311316; called by muse, mutect2, varscan2
- RHPN2 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761330344, COSV54276090; called by muse, mutect2, varscan2
- RILP | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV53961332; called by muse, mutect2, varscan2
- RIN3 | c.2197G>A p.V733M | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775960520, COSV53655615; called by muse, mutect2, varscan2
- RMDN3 | c.1186A>G p.S396G | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV53024597; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 36/118 reads (31%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RORC | c.1193G>A p.S398N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV59095710; called by muse, mutect2, varscan2
- RP1 | c.6160C>G p.L2054V | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV55115757, COSV55126836; called by muse, mutect2
- RPL22 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs751690139, COSV99329550; called by muse, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL5 | c.623T>C p.M208T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV59874252; called by muse, mutect2
- RPS5 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52191336; called by muse, mutect2, varscan2
- RPS6KA1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766775987, COSV64810487; called by muse, mutect2, varscan2
- RREB1 | c.3748del p.H1250Tfs*36 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as COSV100619290; called by mutect2, pindel, varscan2
- RSAD1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148371199, COSV51954634; called by muse, mutect2, varscan2
- RSRC2 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as rs1193679923, COSV59207085; called by muse, mutect2, varscan2
- RTL8C | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.381); catalogued as COSV57060688; called by muse, mutect2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | catalogued as rs747510098; called by mutect2, varscan2
- RUNX3 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100136991, COSV58245893; called by muse, mutect2, varscan2
- RYR2 | c.5218C>T p.P1740S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.191); catalogued as COSV63713556; called by muse, mutect2, varscan2
- SAMD9L | c.4224dup p.Q1409Tfs*49 | Frame Shift Ins (INS) | VAF 70/433 reads (16%) | catalogued as rs759143613; called by mutect2, varscan2
- SAP30BP | c.687del p.G230Afs*34 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs751752121; called by mutect2, pindel, varscan2
- SCAP | c.1477T>A p.S493T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV55565971; called by muse, mutect2, varscan2
- SCAP | c.909G>A p.T303= | Splice Region (SNP) | VAF 6/43 reads (14%) | catalogued as rs768382134, COSV55565982; called by mutect2, varscan2
896 further variants in this file (511 protein-altering or splice-affecting, 353 silent, 32 other) are not listed here.
